Somatic mutation profile of tumor specimen TCGA-DX-A6BB-01A (aliquot TCGA-DX-A6BB-01A-12D-A32I-09) from TCGA case TCGA-DX-A6BB, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 74.3 years (27,150 days).
Specimen TCGA-DX-A6BB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9897bb68-6a8c-406e-b590-a154c363ecce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6BB-10A (Blood Derived Normal), aliquot TCGA-DX-A6BB-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/211af9df-4faa-4c07-897a-5eb9a61c6047

The open-access MAF lists 47 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 11, Nonsense Mutation 3, RNA 1, Splice Region 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs193922185, CM118485, COSV100353754; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 25/29 reads (86%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AGTPBP1 | c.1870C>A p.L624I (on ENST00000357081 / NM_001330701.2; = p.L584I on NM_015239.2) | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as COSV100429107; called by muse, mutect2, varscan2
- ALMS1 | c.2620A>T p.T874S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.036); catalogued as COSV100040757; called by muse, mutect2, varscan2
- CCNH | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56925058, COSV99907100; called by muse, mutect2, varscan2
- CFAP221 | c.1883C>T p.T628I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV99731725; called by muse, mutect2, varscan2
- CHRFAM7A | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs527713019, COSV100241492; called by mutect2, varscan2
- DDX20 | c.1883A>G p.N628S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.056); catalogued as COSV100861926; called by muse, mutect2, varscan2
- DPPA2 | c.318A>C p.Q106H | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV101524723; called by muse, mutect2, varscan2
- FAM120A | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as rs907625530, COSV99464184; called by muse, mutect2
- KANK4 | c.1991A>C p.Q664P | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100586921; called by muse, mutect2, varscan2
- LIG4 | c.2275G>T p.D759Y | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100799660; called by muse, mutect2
- LINGO1 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs199628078; called by muse, mutect2, varscan2
- LTBP2 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100000243, COSV56205118; called by muse, mutect2
- LY75 | c.605A>G p.Y202C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); catalogued as COSV99715725; called by muse, mutect2, varscan2
- MMP9 | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100812308; called by muse, mutect2, varscan2
- MRGPRX4 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs376982271; called by muse, mutect2, varscan2
- MRNIP | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs373245055; called by muse, mutect2, varscan2
- MYCBP2 | c.2716C>T p.Q906* (on ENST00000357337; = p.Q944* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 32/106 reads (30%) | catalogued as COSV100628832; called by muse, mutect2, varscan2
- MYO3B | c.426G>A p.L142= | Splice Region (SNP) | VAF 20/53 reads (38%) | catalogued as COSV100508850, COSV100509518; called by muse, mutect2, varscan2
- PALMD | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1215023778, COSV99586041; called by muse, mutect2
- PCDHB14 | c.122T>A p.I41N | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as COSV99505417; called by muse, mutect2, varscan2
- PKHD1 | c.3574A>T p.I1192F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100580702; called by muse, mutect2, varscan2
- PRPF4B | c.1390A>G p.R464G | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as rs747367615, COSV100527926; called by muse, mutect2, varscan2
- RALGDS | c.2441A>G p.Y814C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100924222; called by muse, mutect2
- SLC39A10 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV62766919; called by muse, mutect2, varscan2
- SMG1 | c.9571C>T p.Q3191* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV101244880; called by muse, mutect2, varscan2
- SNX27 | c.467A>G p.D156G | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100918960; called by muse, mutect2, varscan2
- SYNGR4 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100785084; called by muse, mutect2, varscan2
- TDRD6 | c.1416G>C p.E472D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV100286951; called by muse, mutect2, varscan2
- TOX | c.1302G>T p.Q434H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.735); catalogued as COSV100789260; called by muse, mutect2, varscan2
- TTN | c.41278_41281del p.T13760Sfs*20 (on ENST00000591111; = p.T6336Sfs*20 on NM_003319.4) | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | catalogued as rs758647363; called by mutect2, pindel
- ZEB1 | c.2602G>A p.D868N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.136); catalogued as COSV100313431; called by muse, mutect2, varscan2
- ZFHX4 | c.9098C>G p.S3033* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV51497173; called by muse, mutect2, varscan2
- BPIFB6 | c.264C>T p.F88= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100848464; called by muse, mutect2, varscan2
- CLCN7 | c.2262C>G p.L754= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99246762; called by mutect2, varscan2
- DKK2 | c.741C>T p.Y247= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99567974; called by muse, mutect2, varscan2
- DLX1 | c.111C>T p.H37= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs377533627, COSV100249735; called by muse, mutect2, varscan2
- FANCI | c.3981A>G p.K1327= (on ENST00000310775 / NM_001376911.1; = p.K1267= on NM_018193.3) | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99174438; called by muse, mutect2
- GPX5 | c.450T>C p.S150= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1326264604, COSV101297236; called by muse, mutect2, varscan2
- HEATR6 | c.46C>A p.R16= | Silent (SNP) | VAF 3/53 reads (6%) | catalogued as rs1242367512, COSV99482006, COSV99482314; called by muse, mutect2
- NRDE2 | c.1911G>A p.V637= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100583167; called by muse, mutect2, varscan2
- SLC26A4 | c.2292G>A p.T764= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs139556627, COSV55914548; ClinVar: likely benign; called by muse, mutect2, varscan2
- SOX5 | c.471C>T p.N157= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs149450279; called by mutect2, varscan2
- UBXN10 | c.714C>T p.H238= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100907715; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397614 A>C | 3'Flank (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- RPS26P15 | n.39G>C | RNA (SNP) | VAF 42/95 reads (44%) | called by muse, mutect2, varscan2
